Somatic mutation profile of tumor specimen TCGA-DK-A1AE-01A (aliquot TCGA-DK-A1AE-01A-11D-A13W-08) from TCGA case TCGA-DK-A1AE, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 84.1 years (30,707 days).
Specimen TCGA-DK-A1AE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3756487-45b3-4f5d-b602-b516209161c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A1AE-10A (Blood Derived Normal), aliquot TCGA-DK-A1AE-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3498d57-ec6b-415c-95e3-89b37bac7b08

The open-access MAF lists 129 somatic variants for this specimen: 97 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 30, Nonsense Mutation 7, Frame Shift Ins 3, 5'UTR 1, Splice Site 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 22/60 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67959995, COSV67960100, COSV67961494; called by muse, mutect2, varscan2
- SF3B1 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 32/83 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775623976, COSV59205859, COSV59212489, COSV59228873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs566052180, COSV60912620; called by muse, mutect2, varscan2
- ABCC5 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV55588344; called by muse, mutect2, varscan2
- AC004832.3 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56741583; called by muse, mutect2, varscan2
- ADGRB1 | c.2164G>C p.E722Q | Missense Mutation (SNP) | VAF 98/606 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV60093677; called by muse, mutect2, varscan2
- ADGRL2 | c.4337G>C p.G1446A (on ENST00000370717 / NM_001366005.1; = p.G1390A on NM_012302.4) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.953); catalogued as COSV54658701; called by muse, mutect2, varscan2
- ALOX12B | c.1748C>A p.T583K | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV59871847; called by muse, mutect2, varscan2
- ANGPTL8 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs968623484, COSV52948737; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 70/124 reads (56%) | catalogued as rs758608743; called by mutect2, varscan2
- BRCA1 | c.1337G>C p.R446T | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV58786577; called by muse, mutect2, varscan2
- BRD2 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 85/236 reads (36%) | SIFT tolerated (0.96); PolyPhen benign (0.01); catalogued as COSV66372773; called by muse, mutect2, varscan2
- CFAP97 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV57109774; called by muse, mutect2, varscan2
- CHD2 | c.4978G>T p.D1660Y | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV67707537; called by muse, mutect2, varscan2
- CSMD3 | c.2633T>G p.M878R (on ENST00000297405 / NM_001363185.1; = p.M774R on NM_052900.3) | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV52133653; called by muse, mutect2, varscan2
- CTNNA3 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV65563756; called by muse, mutect2, varscan2
- DNA2 | c.2159C>T p.S720L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV64427981; called by muse, mutect2, varscan2
- DTWD1 | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52071298; called by muse, mutect2, varscan2
- EFEMP1 | c.587C>A p.S196Y | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62615445; called by muse, mutect2, varscan2
- FAM171A1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1290535497, COSV65313996, COSV65318878; called by muse, mutect2, varscan2
- FOS | c.141+1G>A p.X47_splice | Splice Site (SNP) | VAF 49/124 reads (40%) | catalogued as COSV57839230; called by muse, mutect2, varscan2
- GAB1 | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV53755303; called by muse, mutect2, varscan2
- GBP6 | c.1372G>C p.E458Q | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV65010993; called by muse, mutect2, varscan2
- GCC2 | c.3872C>T p.T1291M | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.451); catalogued as rs774543551, COSV59174862; called by muse, mutect2, varscan2
- GNAZ | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs951767417, COSV50737323; called by muse, mutect2
- GRIN2C | c.2038T>G p.F680V | Missense Mutation (SNP) | VAF 122/421 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53110881; called by muse, mutect2, varscan2
- HMGXB4 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV53333314, COSV99330044; called by muse, mutect2, varscan2
- IFT122 | c.1087T>A p.Y363N (on ENST00000348417 / NM_052989.3; = p.Y304N on NM_018262.4) | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56200993, COSV56203981; called by muse, mutect2, varscan2
- IL5RA | c.166C>G p.Q56E | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV56522025; called by muse, mutect2, varscan2
- IMMP1L | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53443422; called by muse, mutect2, varscan2
- INHA | c.431C>A p.A144D | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV54715407; called by muse, mutect2, varscan2
- KIAA0930 | c.410C>A p.S137Y (on ENST00000336156 / NM_001009880.2; = p.S142Y on NM_015264.2) | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV52662592; called by muse, mutect2, varscan2
- KIAA1210 | c.4606T>C p.S1536P | Missense Mutation (SNP) | VAF 54/70 reads (77%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as rs1328086949, COSV68176218; called by muse, mutect2, varscan2
- KIR3DL1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 107/300 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); catalogued as COSV100428561; called by muse, mutect2, varscan2
- KMT2B | c.5837C>T p.S1946L | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); catalogued as COSV55858901; called by muse, mutect2, varscan2
- KMT2D | c.13410G>C p.K4470N | Missense Mutation (SNP) | VAF 95/243 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56422643, COSV56428973; called by muse, mutect2, varscan2
- KMT2D | c.4895C>G p.S1632* | Nonsense Mutation (SNP) | VAF 94/228 reads (41%) | catalogued as CD114126, COSV104396507, COSV99982885; called by muse, mutect2, varscan2
- LMOD2 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752055839, COSV71755586; called by muse, mutect2, varscan2
- LYG2 | c.618C>A p.F206L | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as rs1275151744, COSV60715465; called by muse, mutect2, varscan2
- MAGI2 | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 85/235 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752723914, COSV62641661; called by muse, mutect2, varscan2
- MB21D2 | c.1333G>C p.G445R | Missense Mutation (SNP) | VAF 81/322 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.421); catalogued as COSV66662397; called by muse, mutect2, varscan2
- MDN1 | c.6342G>A p.W2114* | Nonsense Mutation (SNP) | VAF 29/86 reads (34%) | catalogued as COSV65530331; called by muse, mutect2, varscan2
- MEGF6 | c.4615G>A p.A1539T | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.012); catalogued as COSV53887738; called by muse, mutect2, varscan2
- NPAP1 | c.364A>C p.M122L | Missense Mutation (SNP) | VAF 71/210 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV61505467; called by muse, mutect2, varscan2
- NSD1 | c.5951G>T p.R1984L | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM031304, COSV61772992, COSV61784064; called by muse, mutect2, varscan2
- ODF1 | c.80G>T p.C27F | Missense Mutation (SNP) | VAF 77/367 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.979); catalogued as rs781546214, COSV53432030; called by muse, mutect2, varscan2
- OLFM3 | c.184G>A p.D62N (on ENST00000338858 / NM_001288821.1; = p.D42N on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV58796769, COSV58802891; called by muse, mutect2, varscan2
- OR51S1 | c.245T>A p.V82D | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs200985283, COSV59057774; called by muse, mutect2, varscan2
- P2RX2 | c.301C>A p.P101T (on ENST00000343948 / NM_170683.4; = p.A78D on NM_012226.5) | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57674749, COSV57676868; called by muse, mutect2, varscan2
- PBLD | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53265529; called by muse, mutect2, varscan2
- PCDHB3 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 125/376 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.013); catalogued as rs1554272727, COSV50566362; called by muse, mutect2, varscan2
- PCF11 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV53528984; called by muse, mutect2, varscan2
- PNMA8A | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 127/321 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58136296; called by muse, mutect2, varscan2
- POLA2 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 69/252 reads (27%) | catalogued as rs1158684807, COSV55483903; called by muse, mutect2, varscan2
- POLK | c.399G>C p.M133I | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV54033246; called by muse, mutect2, varscan2
- PPARGC1A | c.1970G>A p.R657Q | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as rs1462773399, COSV53525746; called by muse, mutect2, varscan2
- PPARGC1A | c.1223G>C p.R408T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.977); catalogued as COSV53525755; called by muse, mutect2, varscan2
- PROS1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62398029, COSV62398163; called by muse, mutect2, varscan2
- PSD2 | c.1377C>G p.I459M | Missense Mutation (SNP) | VAF 301/805 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51197677; called by muse, mutect2, varscan2
- PSMD1 | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV58077396; called by muse, mutect2, varscan2
- SCG3 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 101/251 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.329); catalogued as COSV55020457; called by muse, mutect2, varscan2
- SCN4A | c.4240G>A p.V1414I | Missense Mutation (SNP) | VAF 64/261 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs369929462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SETD3 | c.1220G>A p.R407K | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59283324; called by muse, mutect2, varscan2
- SLC25A19 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs780717775, COSV55468625; called by muse, mutect2, varscan2
- SMARCC2 | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 152/403 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs779057632, COSV57215540; called by muse, mutect2, varscan2
- SORCS1 | c.1645A>G p.S549G | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53850874, COSV99549572; called by muse, mutect2, varscan2
- SP140 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs868781262, COSV59447740; called by muse, mutect2, varscan2
- SRCAP | c.1774G>C p.E592Q | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52669442; called by muse, mutect2, varscan2
- SRCAP | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 83/216 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52669452; called by muse, mutect2, varscan2
- SRCAP | c.2236G>C p.D746H | Missense Mutation (SNP) | VAF 104/245 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52669464; called by muse, mutect2, varscan2
- TAF2 | c.1170G>T p.E390D | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.331); catalogued as COSV65417308; called by muse, mutect2, varscan2
- TAS2R13 | c.34G>C p.V12L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV66831521; called by muse, mutect2, varscan2
- TEAD4 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 74/211 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV63280351; called by muse, mutect2, varscan2
- TLL2 | c.1528G>C p.E510Q | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV63571436; called by muse, mutect2, varscan2
- TMEM50B | c.446A>G p.K149R | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV70278992; called by muse, mutect2, varscan2
- TNFAIP3 | c.36G>C p.L12F | Missense Mutation (SNP) | VAF 91/238 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.2); catalogued as rs1178250150, COSV52797521; called by muse, mutect2, varscan2
- TNR | c.3245G>A p.R1082H | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.44); PolyPhen probably damaging (1); catalogued as rs745921585, COSV54876456, COSV99688777; called by muse, mutect2, varscan2
- TPM2 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 90/219 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV61405288; called by muse, mutect2, varscan2
- TTN | c.88648G>A p.D29550N (on ENST00000591111; = p.D22126N on NM_003319.4) | Missense Mutation (SNP) | VAF 36/105 reads (34%) | PolyPhen benign (0.027); catalogued as COSV59950770; called by muse, mutect2, varscan2
- TTN | c.88549G>C p.D29517H (on ENST00000591111; = p.D22093H on NM_003319.4) | Missense Mutation (SNP) | VAF 94/269 reads (35%) | PolyPhen possibly damaging (0.542); catalogued as rs397517757, COSV59950803; ClinVar: uncertain significance; called by muse, varscan2
- TTN | c.88502G>A p.G29501D (on ENST00000591111; = p.G22077D on NM_003319.4) | Missense Mutation (SNP) | VAF 78/222 reads (35%) | PolyPhen probably damaging (1); catalogued as rs1559166976, COSV59950843; ClinVar: uncertain significance; called by muse, varscan2
- TTN | c.88003G>A p.D29335N (on ENST00000591111; = p.D21911N on NM_003319.4) | Missense Mutation (SNP) | VAF 40/113 reads (35%) | PolyPhen benign (0.046); catalogued as rs777345218, COSV59950913; called by muse, mutect2, varscan2
- UBE3C | c.3241G>C p.E1081Q | Missense Mutation (SNP) | VAF 111/250 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61952162; called by muse, mutect2, varscan2
- UBR5 | c.7477G>C p.D2493H | Missense Mutation (SNP) | VAF 80/119 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV55282939; called by muse, mutect2, varscan2
- ZADH2 | c.611G>T p.C204F | Missense Mutation (SNP) | VAF 326/1190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59268506; called by muse, mutect2, varscan2
- ZFHX4 | c.8179T>C p.Y2727H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.991); catalogued as COSV50638530; called by muse, mutect2, varscan2
- ZNF142 | c.5641C>G p.P1881A (on ENST00000411696 / NM_001379660.1; = p.P1681A on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.086); catalogued as COSV68743277; called by muse, varscan2
- ZNF234 | c.1845G>C p.Q615H | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV70603037; called by muse, mutect2, varscan2
- ALG2 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK6 | c.1664del p.P555Rfs*23 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- GAA | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 62/279 reads (22%) | called by muse, mutect2, varscan2
- KMT2C | c.8570_8571dup p.A2858Lfs*6 | Frame Shift Ins (INS) | VAF 44/157 reads (28%) | called by mutect2, pindel, varscan2
- KMT2D | c.10684G>T p.E3562* | Nonsense Mutation (SNP) | VAF 82/201 reads (41%) | called by muse, mutect2, varscan2
- SLC24A1 | c.1608dup p.L537Sfs*25 | Frame Shift Ins (INS) | VAF 62/208 reads (30%) | called by pindel, varscan2
- TMEM121B | c.1645C>T p.Q549* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | called by muse, varscan2
- TMEM121B | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.363); called by muse, varscan2
- ZNF142 | c.5554C>T p.Q1852* (on ENST00000411696 / NM_001379660.1; = p.Q1652* on NM_001105537.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 38/115 reads (33%) | called by muse, varscan2
- ADAMTS17 | c.1477C>T p.L493= | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- ANP32D | c.270C>T p.L90= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as COSV56980318; called by muse, mutect2, varscan2
- AR | c.18G>A p.G6= | Silent (SNP) | VAF 41/51 reads (80%) | catalogued as COSV65954366; called by muse, mutect2, varscan2
- AZIN1 | c.417G>A p.L139= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV61479536; called by muse, mutect2, varscan2
- BACE1 | c.630C>G p.L210= | Silent (SNP) | VAF 61/140 reads (44%) | catalogued as COSV57284191; called by muse, mutect2, varscan2
- CDH15 | c.2277G>A p.E759= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as rs765474585, COSV57022820; called by muse, mutect2, varscan2
- CNPY4 | c.693A>G p.G231= | Silent (SNP) | VAF 197/467 reads (42%) | catalogued as COSV53542057; called by muse, mutect2, varscan2
- CORO7 | c.1608G>A p.T536= | Silent (SNP) | VAF 42/151 reads (28%) | catalogued as rs1204758303, COSV52028826, COSV99228065; called by muse, mutect2, varscan2
- ERF | c.1590G>T p.V530= | Silent (SNP) | VAF 51/131 reads (39%) | catalogued as COSV55895304; called by muse, mutect2, varscan2
- FAM71E1 | c.490T>C p.L164= (on ENST00000600100 / NM_001308429.2; = p.L148= on NM_138411.3) | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV58541917; called by muse, mutect2, varscan2
- FGG | c.594G>A p.L198= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as COSV60194859; called by muse, mutect2, varscan2
- GGA3 | c.1620C>T p.L540= (on ENST00000537686 / NM_138619.4; = p.L507= on NM_014001.5) | Silent (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2
- GPR157 | c.870C>G p.L290= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as COSV66233300; called by muse, mutect2, varscan2
- HCN4 | c.1254C>A p.I418= | Silent (SNP) | VAF 73/176 reads (41%) | catalogued as COSV56082203; called by muse, mutect2, varscan2
- KCNT2 | c.609A>T p.I203= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV54070317; called by muse, mutect2
- MED24 | c.2604C>A p.A868= | Silent (SNP) | VAF 85/228 reads (37%) | catalogued as COSV56640225; called by muse, mutect2, varscan2
- MRGPRE | c.417G>A p.L139= | Silent (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- MRPL14 | c.405C>T p.S135= | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as COSV64394467; called by muse, mutect2, varscan2
- PLIN5 | c.1248G>A p.Q416= | Silent (SNP) | VAF 161/382 reads (42%) | catalogued as COSV67850497; called by muse, mutect2, varscan2
- PRAMEF19 | c.1056G>A p.Q352= | Silent (SNP) | VAF 209/701 reads (30%) | catalogued as COSV101069388; called by muse, mutect2, varscan2
- RPP25 | c.405C>T p.L135= | Silent (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- SCN10A | c.4962C>T p.L1654= | Silent (SNP) | VAF 52/149 reads (35%) | catalogued as COSV71860764; called by muse, mutect2, varscan2
- SFRP5 | c.624C>A p.I208= | Silent (SNP) | VAF 116/358 reads (32%) | catalogued as COSV56603883; called by muse, mutect2, varscan2
- SLC4A1AP | c.1431G>A p.L477= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as rs1333978869, COSV58134187; called by muse, mutect2, varscan2
- SNX30 | c.954C>T p.D318= | Silent (SNP) | VAF 40/147 reads (27%) | catalogued as rs915439997, COSV65292389; called by muse, mutect2, varscan2
- SVIL | c.6264C>G p.L2088= (on ENST00000355867 / NM_021738.3; = p.L1662= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV63441551; called by muse, mutect2, varscan2
- SYT1 | c.45C>A p.V15= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV54039038; called by muse, mutect2, varscan2
- TTN | c.88182G>A p.L29394= (on ENST00000591111; = p.L21970= on NM_003319.4) | Silent (SNP) | VAF 108/294 reads (37%) | catalogued as COSV59950880; called by muse, mutect2, varscan2
- USP37 | c.1320G>T p.L440= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV51442107; called by muse, varscan2
- ZNF250 | c.501G>C p.L167= | Silent (SNP) | VAF 117/514 reads (23%) | catalogued as COSV52968589; called by muse, mutect2, varscan2
- HERC2P3 | n.1814C>T | RNA (SNP) | VAF 10/44 reads (23%) | catalogued as rs1412427220; called by mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 39/99 reads (39%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
